Somatic mutation profile of tumor specimen MP2PRT-PAWCSN-TMP1-A (aliquot MP2PRT-PAWCSN-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAWCSN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,978 days).
Specimen MP2PRT-PAWCSN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 196e63ea-10f5-4126-857b-94ac41c58104.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCSN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCSN-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/111727e5-a946-4177-876f-fa282f2d7a5a

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 1, Nonsense Mutation 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 29/251 reads (12%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CACNA1G | c.6875G>A p.G2292D | Missense Mutation (SNP) | VAF 217/681 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs751060300, COSV61720106; called by muse, mutect2, varscan2
- CBLL2 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 51/370 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs746442308, COSV60368818; called by muse, mutect2, varscan2
- CCDC171 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 117/271 reads (43%) | catalogued as rs771168836, COSV99899720; called by muse, mutect2, varscan2
- CD163L1 | c.2449C>T p.R817C | Missense Mutation (SNP) | VAF 34/488 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs763534001, COSV58015762; called by muse, mutect2
- CPXM2 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.166); catalogued as rs745908668, COSV53864812; called by muse, mutect2
- ENPEP | c.2338G>A p.V780I | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as rs776505588; called by muse, mutect2, varscan2
- EYS | c.5359G>A p.V1787I | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs756545975; called by muse, mutect2
- FLT3 | c.1778_1779insGGA p.V592_D593insE | In Frame Ins (INS) | VAF 75/234 reads (32%) | catalogued as COSV54042756, COSV54062464, COSV54079441; called by mutect2, pindel, varscan2
- ITSN1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 118/616 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750087030, COSV66082829; called by muse, varscan2
- KRT84 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 166/535 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs200827366; called by muse, mutect2, varscan2
- NR3C2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 116/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100679295; called by muse, mutect2, varscan2
- PNPLA3 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756325486; called by muse, mutect2, varscan2
- PSG4 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs540660899, COSV54939642; called by muse, mutect2, varscan2
- PTCHD3 | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as rs1177566796; called by muse, mutect2
- TBC1D9 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 116/582 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1368494936, COSV71308305; called by muse, mutect2, varscan2
- WNT4 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1201538116, COSV99268595; called by muse, mutect2, varscan2
- APOB | c.11009G>A p.R3670K | Missense Mutation (SNP) | VAF 35/470 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.062); called by muse, mutect2
- PTPRE | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 175/494 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC6 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 35/675 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.199); called by muse, mutect2
- UBASH3A | c.857A>C p.Q286P | Missense Mutation (SNP) | VAF 76/443 reads (17%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- VPS51 | c.1462G>T p.G488C | Missense Mutation (SNP) | VAF 140/283 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DGKD | c.3285C>T p.S1095= (on ENST00000264057 / NM_152879.3; = p.S1051= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 86/384 reads (22%) | catalogued as rs764403727, COSV51037072; called by muse, mutect2, varscan2
- DNAH11 | c.7878G>A p.P2626= | Silent (SNP) | VAF 85/208 reads (41%) | catalogued as rs748463983, COSV60938783, COSV60951974; called by muse, mutect2, varscan2
- JPH3 | c.528G>A p.A176= | Silent (SNP) | VAF 216/439 reads (49%) | catalogued as rs377433473; called by muse, varscan2
- LRRC8E | c.15C>T p.A5= | Silent (SNP) | VAF 87/255 reads (34%) | catalogued as rs780909604; called by muse, mutect2, varscan2
- PKHD1L1 | c.2913A>G p.R971= | Silent (SNP) | VAF 61/332 reads (18%) | called by muse, mutect2, varscan2
- PLXNB3 | c.1011C>T p.G337= | Silent (SNP) | VAF 19/615 reads (3%) | catalogued as rs1434936951; called by muse, mutect2
- TPSG1 | c.318C>T p.T106= | Silent (SNP) | VAF 142/318 reads (45%) | catalogued as rs1025739981; called by muse, mutect2, varscan2
- ELMOD3 | c.943+174_943+175del | Intron (DEL) | VAF 74/432 reads (17%) | called by mutect2, pindel*, varscan2*
